Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A0ZP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A0ZP-01A (Primary Tumor).

[page 1 of 7]
DIAGNOSIS:

A. Mesentery, cecum, biopsy: Involved by metastatic adenocarcinoma.

B. Uterus, hysterectomy: FIGO grade III (of III) endometrial adenocarcinoma, serous type identified forming a mass (3.8 x 3.3 x 0.9 cm) circumferentially involving the endometrial cavity and arising in association with a polyp. The tumor invades 0.5 cm into the myometrium (total wall thickness 1.6 cm). The tumor does not involve the endocervix. Lymphovascular space invasion is not identified. Anterior uterine serosa is involved by metastatic adenocarcinoma. The cul de sac shows endosalpingiosis. The left tube and ovary show endometriosis. The right tube and ovary and cervix are without diagnostic abnormality. There is a single intramural leiomyoma (5.3 cm in greatest dimension) identified in the myometrium.

C, D, E, F. Lymph nodes, left pelvic, excision: Multiple (3 external iliac, 4 internal iliac, 2 common iliac, 17 obturator) left pelvic lymph nodes are negative for tumor.

G, H, I, J. Lymph nodes, right pelvic, excision: Multiple (6 external iliac, 5 internal iliac, 2 common iliac, 12 obturator) right pelvic lymph nodes are negative for tumor.

K, L, N, O. Lymph nodes, left and right para-aortic, excision: Multiple (9 left, 1 right) para-aortic lymph nodes above the inferior mesenteric artery and multiple (2 left, 7 right) para-aortic lymph nodes below the inferior mesenteric artery are

[page 2 of 7]
negative for tumor.

M, P. Gonadal vessels, left and right, excision: The left and right gonadal vessels are negative for tumor

Q.Soft tissue, pyloric region, excision: Benign epithelial cyst (0.7 x 0.6 x 0.6 cm). Negative for neoplasm.

R.Omentum, omentectomy: Negative for neoplasm. A single omental lymph node is negative for tumor.

This final pathology report is based on the gross/macrosopic examination and frozen section histologic evaluation of the specimen(s).

GROSS DESCRIPTION:

A. Received fresh labeled "cecal mesentery" is a 0.3 x 0.2 x 0.2 cm tan-red tissue fragment. All submitted.

B.Received fresh labeled "uterus, left and right tubes and ovaries" is a 165.0 gram uterus with attached bilateral tubes and ovaries and an unremarkable cervix. The uterine serosa has focal fibrous adhesions suspicious for endometriosis. There is a 3.8 x 3.3 x 0.9 cm mass filling the entire endometrial cavity with 1.6 cm myometrial thickness. There is a single intramural leiomyoma 5.3 cm in greatest dimension. There is a 1.2 x 0.8 x 0.7 cm right ovary with a 9.7 x 0.4 cm right fallopian tube with adhesions. There is a 2.2 x 1.6 x 0.7cm left ovary with a ragged outer surface and a solid cut surface with adhesions with a 7.8 x 0.6 cm left fallopian tube with adhesions. Representative sections submitted.

[page 3 of 7]
C. Received fresh labeled "left pelvic external lymph nodes" is
a 5.5 x 4.7 x 1.3 cm aggregate of adipose and lymphatic tissue. All
lymphatic tissue submitted.

D. Received fresh labeled "left pelvic internal lymph nodes" is
a 2.5 x 1.3 x 0.8 cm aggregate of adipose and lymphatic tissue. All
lymphatic tissue submitted.

E. Received fresh labeled "left pelvic common lymph nodes" is a
3.5 x 2.7 x 1.4 cm aggregate of adipose and lymphatic tissue. All
lymphatic tissue submitted.

F. Received fresh labeled "left pelvic obturator lymph nodes" is
a 5.7 x 4.5 x 2.0 cm aggregate of adipose and lymphatic tissue. All
lymphatic tissue submitted.

G. Received fresh labeled "right pelvic external lymph node" is
a 5.7 x 4.7 x 1.8 cm aggregate of adipose and lymphatic tissue. All
lymphatic tissue submitted.

H. Received fresh labeled "right pelvic internal lymph node" is
a 1.8 x 1.6 x 0.9 cm aggregate of adipose and lymphatic tissue. All
lymphatic tissue submitted.

I. Received fresh labeled "right pelvic common lymph node" is a
2.0 x 1.4 x 0.9 cm aggregate of adipose and lymphatic tissue. All
lymphatic tissue submitted.

J. Received fresh labeled "right pelvic obturator" is an
(5.7 x
5.4 x 2.4 cm) aggregate of adipose and lymphatic tissue.
All

[page 4 of 7]
lymphatic tissue submitted.

K. Received fresh labeled "right para aortic lymph nodes above IMA" is a 2.0 x 1.3 x 0.8 cm aggregate of adipose and lymphatic tissue.

All lymphatic tissue submitted.

L. Received fresh labeled "right para aortic lymph nodes below

IMA" is a 3.2 x 2.0 x 1.3 cm aggregate of adipose and lymphatic

tissue. All lymphatic tissue submitted.

M. Received fresh labeled "right gonadal vessel" is a 8.3 cm in

length by 0.4 cm in diameter portion of unremarkable blood vessel.

A representative section is submitted.

N. Received fresh labeled "left para aortic lymph nodes above

IMA" is a 3.4 x 2.3 x 0.9 cm aggregate of adipose and lymphatic

tissue. All lymphatic tissue submitted.

O. Received fresh labeled "left para aortic lymph node below

IMA" is a 2.4 x 1.8 x 1.4 cm aggregate of adipose and lymphatic

tissue. All lymphatic tissue submitted.

P. Received fresh labeled "left gonadal vessel" is a 8.8 cm in

length by 0.4 cm in diameter portion of unremarkable blood vessel.

A representative section is submitted.

Q. Received fresh labeled "pyloric cyst" is a 0.7 x 0.6 x 0.6 cm

cystic nodule. All submitted. Grossed by ' .

R. Received fresh labeled "omentum" is a 44.5 x 22.0 x 1.6 cm

portion of omentum. No masses are identified grossly. A lymph node

is identified. Representative sections are submitted.

[page 5 of 7]
BLOCK SUMMARY:

Part A: Cecal mesentery

- 1 Cecal mesentery

Part B: Uterus, tubes, ovaries

- 1 Surface of Lt ovary
- 2 Lt ovary
- 3 Anterior uterine serosa
- 4 Anterior uterine serosa
- 5 Uterine cul de sac
- 6 Lt fallopian tube
- 7 Endometrium
- 8 Endometrium
- 9 Endometrium
- 10 Endometrium
- 11 Endometrium
- 12 Lower uterine segment
- 13 Cervix
- 14 Myometrium (leiomyoma)
- 15 Rt fallopian tube
- 16 Rt ovary

Part C: Left pelvic lymph node external

- 1 Lt external LNs 2
- 2 Lt external LN 1

Part D: Left pelvic lymph node internal

- 1 Lt internal LN 1

Part E: Left pelvic lymph node common

- 1 Lt common LN 1
- 2 Lt common LN (1of2)
- 3 Lt common LN (2of2)

Part F: Left pelvic lymph node obturator

- 1 Lt obturator LNs 3
- 2 Lt obturator LNs 4
- 3 Lt obturator LNs 4
- 4 Lt obturator LNs 3

[page 6 of 7]
- 5 Lt obturator LN (1of2)
- 6 Lt obturator LN (2of2)
- 7 Lt obturator LNs 3
- 8 Lt obturator LN (1of2)
- 9 Lt obturator LN (2of2)

Part G: Right pelvic lymph node external

- 1 Rt external LNS 2
- 2 Rt external LNS 1
- 3 Rt external LNS 1
- 4 Rt external LNS 2

Part H: Right pelvic lymph node internal

- 1 Rt internal LNS 2
- 2 Rt internal LNS 3

Part I: Right pelvic lymph node common

- 1 Rt common pelvic LNs 2

Part J: Right pelvic lymph node obturator

- 1 Rt obturator pelvic LNs 2
- 2 Rt obturator pelvic LNs 3
- 3 Rt obturator pelvic LN 1
- 4 Rt obturator pelvic LNs 2
- 5 Rt obturator pelvic LNs 2
- 6 Rt obturator pelvic LN 1
- 7 Rt obturator pelvic LN 1

Part K: Right Para-aortic Nodes above IMA

- 1 Rt above IMA LN 1

Part L: Right Para-aortic Nodes below IMA

- 1 Rt below IMA LN 4
- 2 Rt below IMA LN 2
- 3 Rt below IMA 1

Part M: Gonadal vessel

- 1 Rt gonadal vessel

Part N: Left Para-aortic Lymph Nodes above IMA

- 1 Lt above IMA LNs 2
- 2 Lt above IMA LNs 2
- 3 Lt above IMA LN2 4

Part O: Left Para-aortic Lymph Nodes below IMA

- 1 Lt below IMA LN 1
- 2 Lt below IMA LN (1of2)

[page 7 of 7]
3 Lt below IMA LN (2of2)

Part P: Left Gonadal vessels
1 Lt gonadal vessels

Part Q: Pyloric cyst
1 Pyloric cyst

Part R: Omentum
1 Omentum
2 Omentum LN 1

Source: NCI Genomic Data Commons file dfb6629b-0e94-4349-b896-176bf02eb574 (TCGA-D1-A0ZP.FD46BB74-914F-4B4E-819A-5AD5F4548672.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).